Somatic mutation profile of tumor specimen 0E1KOC from CCDI case PBCVGB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1KOC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aba5df38-bb96-4ce5-a3e4-2ce0d046402c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1KO0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bd452e3-714f-436e-ba40-7873f46b72bc

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 2, Intron 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOC1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 40/660 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs367665701; called by muse, mutect2
- OSBPL7 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 331/703 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1476368982; called by muse, mutect2, varscan2
- ACADVL | c.277+1G>A p.X93_splice | Splice Site (SNP) | VAF 260/549 reads (47%) | called by muse, mutect2, varscan2
- SMARCB1 | c.645_646insCC p.V216Pfs*6 (on ENST00000263121; = p.V262Pfs*6 on NM_003073.5) | Frame Shift Ins (INS) | VAF 172/234 reads (74%) | called by mutect2, varscan2
- COQ9 | c.52C>T p.L18= | Silent (SNP) | VAF 255/472 reads (54%) | catalogued as rs556734293; called by muse, mutect2, varscan2
- LAMA3 | c.3426C>T p.P1142= | Silent (SNP) | VAF 445/877 reads (51%) | called by muse, mutect2, varscan2
- RREB1 | c.2277C>T p.G759= | Silent (SNP) | VAF 152/339 reads (45%) | catalogued as rs1171683988, COSV100619888; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 55/1343 reads (4%) | called by muse, mutect2
- SMG1 | c.7038G>A p.T2346= | Silent (SNP) | VAF 338/961 reads (35%) | catalogued as rs755074367, COSV67174006; called by muse, mutect2, varscan2
- PRKCB | c.174-77C>T | Intron (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- USHBP1 | c.1047-100C>A | Intron (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
